HCMI case HCM-BROD-0702-C43 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/71dd56c3-0048-4ec9-89cb-53b5e966255a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1948.

Diagnoses (2)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C43.9; Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Age at diagnosis: 69.3 years (25,295 days); AJCC staging edition: 7th; AJCC pathologic T: T4; AJCC pathologic N: N3; AJCC pathologic M: M0.
2. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/6; ICD-10 code: C79.2; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Classification of tumor: metastasis; Age at diagnosis: 70.7 years (25,815 days); Days to diagnosis: 520 days (1.4 years); Satellite nodule present: Present.
   Pathology details: Breslow thickness category: >1.0-2.0 mm; Lymph nodes positive: 1; Lymph nodes tested: 2; Perineural invasion present: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Ipilimumab + Pembrolizumab; Treatment intent type: Maintenance Therapy; Days to treatment start: 304 days; Days to treatment end: 612 days (1.7 years); Treatment outcome: Progressive Disease.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 545.

Molecular and laboratory tests
- BRAF mutation, nos: Negative.

Other clinical attributes
- Timepoint category: Initial Diagnosis; BMI: 23.

Family history
- Relationship type: First Degree Relative, NOS.

Biospecimens (2 samples)
- Sample HCM-BROD-0702-C43-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Sample HCM-BROD-0702-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 14.
